Somatic mutation profile of tumor specimen TCGA-W5-AA2W-01A (aliquot TCGA-W5-AA2W-01A-11D-A417-09) from TCGA case TCGA-W5-AA2W, project TCGA-CHOL (Cholangiocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Cholangiocarcinoma; Tissue or organ of origin: Intrahepatic bile duct; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 31.3 years (11,438 days).
Specimen TCGA-W5-AA2W-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1152fb45-8b6b-495b-867b-2df50f9b17b7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-W5-AA2W-10A (Blood Derived Normal), aliquot TCGA-W5-AA2W-10A-01D-A41A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a95c7f26-3d28-498b-b7e2-f13702f4c9d8

The open-access MAF lists 22 somatic variants for this specimen: 21 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 15, Nonsense Mutation 2, Splice Site 2, Frame Shift Del 1, Silent 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHD7 | c.2504_2508del p.Y835Sfs*14 | Frame Shift Del (DEL) | VAF 37/87 reads (43%) | catalogued as rs886040982; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- BAD | c.146G>A p.S49N | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.122); catalogued as rs766061149; called by muse, mutect2, varscan2
- BAP1 | c.745A>T p.K249* | Nonsense Mutation (SNP) | VAF 8/11 reads (73%) | catalogued as COSV56241795; called by muse, mutect2, varscan2
- CDC27 | c.940G>A p.G314R | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs200268612; called by muse, mutect2, varscan2
- DNAH2 | c.1669C>T p.R557C | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV50013816; called by muse, mutect2, varscan2
- MPZL3 | c.578G>A p.R193K | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99636434; called by muse, mutect2, varscan2
- MYO3A | c.593C>T p.A198V | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56345814; called by muse, mutect2
- SPTAN1 | c.5633A>G p.N1878S | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.887); catalogued as rs200248814; ClinVar: likely benign; called by muse, mutect2, varscan2
- ZNF839 | c.1138G>A p.V380M (on ENST00000558850 / NM_001267827.1; = p.V496M on NM_018335.5) | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.753); catalogued as rs778851361, COSV99216203; called by muse, mutect2, varscan2
- AKAP13 | c.3949G>A p.E1317K | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.265); called by mutect2, varscan2
- AP2S1 | c.110C>A p.A37D | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.577); called by muse, mutect2
- CASK | c.1066G>A p.E356K | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- CATSPERB | c.1433-1G>A p.X478_splice | Splice Site (SNP) | VAF 18/44 reads (41%) | called by muse, mutect2, varscan2
- GFM1 | c.81_81+11del p.X27_splice | Splice Site (DEL) | VAF 20/52 reads (38%) | called by mutect2, pindel, varscan2
- KRTAP12-2 | c.143T>C p.V48A | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MYO9A | c.2538C>G p.F846L | Missense Mutation (SNP) | VAF 97/174 reads (56%) | SIFT tolerated (0.26); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- NAV3 | c.570_572del p.Q191del | In Frame Del (DEL) | VAF 8/35 reads (23%) | called by pindel, varscan2
- NKX2-2 | c.738_740dup p.Q246_Y247ins* | Nonsense Mutation (INS) | VAF 7/23 reads (30%) | called by mutect2, pindel, varscan2
- OR2L13 | c.395C>T p.P132L | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.322); called by muse, mutect2, varscan2
- OTUD5 | c.627C>A p.D209E | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMEM87A | c.1271T>C p.M424T | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.579); called by muse, mutect2
- PIP5KL1 | c.669C>T p.C223= (on ENST00000388747 / NM_001135219.2; = p.C20= on NM_173492.1) | Silent (SNP) | VAF 20/55 reads (36%) | catalogued as rs747570323, COSV100304751; called by muse, mutect2, varscan2
